CCDI case PBCPML — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/c4a4da61-27b8-4f57-8212-de0066ab7449

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 18.1 years (6,593 days).

Biospecimens (3 samples)
- Sample 0DX4ER: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4F5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX4FO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
